Gene-level copy-number profile of tumor specimen C3L-09396-02 from CPTAC case C3L-09396, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.8 years (25,137 days).
Specimen C3L-09396-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1a68c747-35da-446e-9f4f-e9ca5e8c9f23.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09396-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/e1962472-0048-4d7a-81d0-4cb748b26170

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 560; copy number 1: 337; copy number 2: 17,627; copy number 3: 24,160; copy number 4: 10,838; copy number 5: 3,551; copy number 6: 393; copy number 7: 825; copy number 8: 300; copy number 9: 185; copy number 10: 128; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–3): AC104164.2, MIR548BB.
- chr15:21,298,233–21,946,641, 37 genes: AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr15:21,980,277–22,095,857, 9 genes: OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,440 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,563,489–22,921,500, 9 genes, copy number 10: EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253.
- chr1:23,428,563–23,640,568, 6 genes, copy number 9: ASAP3, E2F2, AL021154.1, ID3, AL450043.1, MDS2.
- chr1:143,419,625–154,194,648, 467 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr1:154,993,586–156,916,434, 117 genes, copy number 8 (broad region; genes not listed).
- chr1:157,830,911–157,898,256, 1 gene, copy number 7 (within-gene range 6–7): CD5L.
- chr1:157,925,065–164,980,137, 232 genes, copy number 7–10 (broad region; genes not listed).
- chr1:166,747,379–168,376,876, 44 genes, copy number 7–13: RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2, POU2F1, AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557.
- chr1:168,401,483–168,407,274, 1 gene, copy number 8: AL022100.2.
- chr5:177,592,203–177,713,969, 5 genes, copy number 7–9 (within-gene range 4–9): TMED9, B4GALT7, AC139795.2, AC139795.1, AC138819.1.
- chr10:134,465–1,737,525, 24 genes, copy number 8–9 (within-gene range 5–9): ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1.
- chr15:21,015,048–21,015,078, 1 gene, copy number 7: IGHD2OR15-2B.
- chr19:54,200,809–54,249,003, 1 gene, copy number 7 (within-gene range 5–7): RPS9.
- chr19:54,216,278–58,605,223, 329 genes, copy number 7 (broad region; genes not listed).
- chr20:30,278,906–31,645,006, 38 genes, copy number 7: LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2.
- chr20:32,355,053–37,241,619, 165 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
